Somatic mutation profile of tumor specimen TCGA-2J-AAB8-01A (aliquot TCGA-2J-AAB8-01A-12D-A40W-08) from TCGA case TCGA-2J-AAB8, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,028 days).
Specimen TCGA-2J-AAB8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6639865-195c-474d-8b3e-b0030fa92b0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AAB8-10A (Blood Derived Normal), aliquot TCGA-2J-AAB8-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7771b46-d56a-41fa-b053-aafe84542d43

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 22/239 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- MEGF10 | c.2104+1G>A p.X702_splice | Splice Site (SNP) | VAF 23/234 reads (10%) | catalogued as rs1298663120, COSV57255045, COSV99175528; ClinVar: likely pathogenic; called by muse, mutect2
- ALK | c.3635G>A p.R1212H | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143790259, COSV66560358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP5 | c.3780del p.F1260Lfs*61 (on ENST00000345122 / NM_001030055.2; = p.F1259Lfs*61 on NM_001173.3) | Frame Shift Del (DEL) | VAF 96/480 reads (20%) | catalogued as rs1200602327; called by mutect2, pindel, varscan2
- ATP2B2 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 58/904 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776369165; called by muse, mutect2
- ATP8B4 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376889811, COSV52721344; called by muse, mutect2, varscan2
- COL3A1 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58596467; called by muse, mutect2
- CSMD3 | c.7681C>T p.R2561W (on ENST00000297405 / NM_001363185.1; = p.R2457W on NM_052900.3) | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756318986, COSV52243175; called by muse, mutect2, varscan2
- DDHD2 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101240780, COSV68157340; called by muse, mutect2
- DLG4 | c.1180C>G p.P394A (on ENST00000399506 / NM_001321075.3; = p.P437A on NM_001365.4) | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100263966; called by muse, mutect2, varscan2
- EVPL | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs752763898, COSV56906916; called by muse, mutect2
- FASTKD1 | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.264); catalogued as COSV101328542; called by muse, mutect2
- GMDS | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66428943; called by muse, mutect2
- GSDMD | c.1396A>T p.M466L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99369595; called by muse, mutect2
- HCN4 | c.2265C>A p.C755* | Nonsense Mutation (SNP) | VAF 38/235 reads (16%) | catalogued as COSV99984170; called by muse, mutect2, varscan2
- HNRNPA1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); catalogued as COSV99267842; called by muse, mutect2, varscan2
- IKZF2 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100563828; called by muse, mutect2
- ITGA7 | c.2870G>A p.R957Q (on ENST00000555728; = p.R913Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as rs755263823, COSV99153483; called by muse, mutect2
- KCNA4 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 62/846 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100069232, COSV60252907; called by muse, mutect2
- LATS2 | c.1624C>A p.Q542K | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV101231666; called by muse, mutect2, varscan2
- MAP3K21 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 35/307 reads (11%) | catalogued as COSV64041616; called by muse, mutect2
- MST1R | c.1606T>C p.C536R | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619547; called by muse, mutect2, varscan2
- NUP50 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs563414031, COSV61661828; called by muse, mutect2
- NWD1 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 88/551 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1432547715, COSV100343592; called by muse, mutect2, varscan2
- OR2M4 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs144805988; called by muse, mutect2, varscan2
- PHB | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100303247; called by muse, mutect2, varscan2
- PHEX | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs768400503, COSV101039549, COSV65078293; called by muse, mutect2, varscan2
- RTN4 | c.2327T>G p.F776C | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as COSV100463873; called by muse, mutect2, varscan2
- SMAD4 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 23/469 reads (5%) | catalogued as COSV61686624; called by muse, mutect2
- SPARCL1 | c.1221C>T p.A407= | Splice Region (SNP) | VAF 36/295 reads (12%) | catalogued as COSV99215855; called by muse, mutect2, varscan2
- STOX2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100409215; called by muse, mutect2, varscan2
- THBS4 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 34/610 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV100644417; called by muse, mutect2
- TJP1 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 35/331 reads (11%) | catalogued as COSV100633124; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 118/488 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TP53 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 63/306 reads (21%) | catalogued as COSV52661795, COSV52683537, COSV52718793; called by muse, mutect2, varscan2
- ZFHX4 | c.4713A>T p.K1571N | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1203626604, COSV99266973, COSV99269778; called by muse, mutect2
- ZFPM2 | c.117C>G p.D39E | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV101343546; called by muse, mutect2, varscan2
- DISP3 | c.219T>G p.C73W | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- HMX2 | c.164_170del p.E55Afs*114 | Frame Shift Del (DEL) | VAF 17/137 reads (12%) | called by mutect2, pindel, varscan2
- KRBA1 | c.3093A>G p.*1031Wext*115 | Nonstop Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ADCY3 | c.2202C>T p.P734= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs970587123, COSV99569046; called by muse, mutect2
- CRKL | c.417C>A p.A139= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as COSV100574197, COSV62883573; called by muse, mutect2
- EPOR | c.336C>T p.A112= | Silent (SNP) | VAF 37/283 reads (13%) | catalogued as COSV99710291; called by muse, mutect2, varscan2
- GSG1 | c.684G>A p.A228= (on ENST00000651961 / NM_001080555.4; = p.D234N on NM_031289.5) | Silent (SNP) | VAF 89/572 reads (16%) | catalogued as rs747128004, COSV52197363; called by muse, mutect2, varscan2
- HAPLN1 | c.639C>T p.G213= | Silent (SNP) | VAF 28/380 reads (7%) | catalogued as COSV57151696, COSV99165174; called by muse, mutect2
- IL23R | c.1518C>G p.S506= | Silent (SNP) | VAF 13/285 reads (5%) | catalogued as COSV100724911; called by muse, mutect2
- LATS2 | c.1623G>A p.E541= | Silent (SNP) | VAF 43/369 reads (12%) | catalogued as rs754558907, COSV101231667; called by muse, mutect2, varscan2
- MAPT | c.867C>T p.S289= (on ENST00000262410 / NM_001377265.1; = p.S214= on NM_016835.4) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99291245; called by muse, mutect2
- MUC17 | c.12546G>A p.E4182= | Silent (SNP) | VAF 35/462 reads (8%) | catalogued as rs753376856, COSV100074908; called by muse, mutect2
- SPTLC1 | c.1344C>T p.V448= | Silent (SNP) | VAF 41/386 reads (11%) | catalogued as COSV99365091; called by muse, mutect2, varscan2
- STOX2 | c.2379G>A p.E793= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100409219; called by muse, mutect2
- UMOD | c.1236C>T p.I412= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as COSV100208643; called by muse, mutect2
